Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5878, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5878-01A (Primary Tumor).

[page 1 of 4]
Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

Ref. Physician: [REDACTED]

Patient Address: [REDACTED]

Ref. Source: [REDACTED]

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

[REDACTED] h left renal mass; s/p left nephrectomy and lymph node dissection.

Specimens Submitted:

1: SP: Kidney and adrenal gland, left; radical nephrectomy [REDACTED]

2: SP: Ureter, segment of distal left; excision [REDACTED]

3: SP: Lymph nodes, para-aortic and preaortic; excision [REDACTED]

4: SP: Lymph nodes, left common iliac; excision [REDACTED]

5: SP: Lymph nodes, interaortocaval; excision [REDACTED]

DIAGNOSIS:

1. SP: Kidney and adrenal gland, left; radical nephrectomy [REDACTED]

Tumor Type:

Renal cell carcinoma - Papillary type
type2

Tumor Size:

Greatest diameter is 5.8 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion is present.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Multiple benign cortical cysts

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

2. SP: Ureter, segment of distal left; excision [REDACTED]

Benign segment of ureter.

[page 2 of 4]
3. SP:Lymph nodes, para-aortic and preaortic; excision

Lymph Nodes:

Number of nodes examined:9

Number of metastatic nodes:1

The largest metastatic node is 0.6cm

Perinodal (extracapsular) extension identified

Two other separate nodules of tumor, the larger measuring 5.5 cm in diameter, are identified. Their representing lymph nodes completely replaced by tumor cannot be excluded.

4. SP:Lymph nodes, left common iliac;excision:

Lymph Nodes:

Not involved

Number of nodes examined:6

5. SP:Lymph nodes, interaortocaval; excision

Lymph Nodes:

Not involved

Number of nodes examined:9

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain

Comment

RECUT

RECUT

RECUT

RECUT

RECUT

Gross Description:

1). The specimen is received fresh labeled "left kidney and adrenal gland" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 370 g in total. The kidney measures 11.5 x 6 x 4 cm. The attached ureter measures 9.5 cm in length and 0.5 cm in diameter. The attached renal vein measures 1.5 cm in length and 0.8 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified measuring 4 x 1.5 x 1.2 cm. The kidney is inked black and bivalved to reveal a tumor mass located in the upper pole measuring 5.8 x 4.5 x 3 cm. The mass on sectioning has a lobulated appearance, variegated cut surface showing tan-yellow areas admixed with areas of hemorrhage and foci of necrosis. Grossly it is confined within the kidney and does not extend beyond the capsule. In the mid aspect of the kidney, and 1 cm away from the tumor mass is a serous fluid-filled cyst, measuring 5 x 5 x 4 cm. The cyst wall is smooth. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined corticomedullary junction. The cortex measures 0.8 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

FSC - frozen section control

UVM -- ureteral and vessel margins

TC- tumor in relation to kidney capsule

[page 3 of 4]
THF-- hilar fat, closest to tumor
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
TP -- tumor and renal pelvis
C- cyst
K -- representative sections kidney
AD -- adrenal gland

2) The specimen is received in formalin, labeled "Segment distal left ureter". It consists of a segment of pink tubular tissue measuring 2.1 cm in length with a diameter of 0.3 cm. A stapled end is noted. The specimen is inked black. It is otherwise grossly unremarkable. The specimen is totally embedded.

Summary of sections:
SM-shaved stapled margin
R-remainder

3). The specimen is received in formalin, labeled "para-aortic and pre-aortic lymph nodes", and consists of three pieces of fatty tissue measuring 7.5 x 5 x 2.5 cm in aggregate. On sectioning, there is a soft tan nodule measuring 4 x 2.15 cm, which on sectioning has areas of necrosis. There is a second 5.5 x 3 x 2.5 cm nodule that on sectioning shows tan yellow areas. In addition, there are smaller nodules measuring from 0.5 to 1 cm in greatest dimension. The small nodules are entirely submitted.

Summary of sections:
L1- lymph node, 5.5 cm, representatively
L2-lymph node, 4 cm representatively
LNs-smaller nodes

4) The specimen is received in formalin, labeled "Left common iliac lymph nodes". It consists of multiple palpable lymph nodes ranging in size from 0.5 to 1.4 cm in greatest dimension. All possible nodal tissue is totally embedded in two cassettes.

Summary of sections:
LN-lymph nodes

5) The specimen is received in formalin, labeled "Inter-aortocaval nodes". It consists of multiple small lymph nodes encased in fat ranging in size from 0.4 to 0.8 cm in greatest dimension. All possible nodal tissue is totally embedded in three cassettes.

Summary of sections:
LN-lymph nodes

Summary of Sections:

Part 1: SP: Kidney and adrenal gland, left; radical nephrectomy

Block	Sect. Site	PCs
1	AD	1
2	C	3
1	FSC	1
1	K	1
3	TC	3
1	THF	1
1	TK	1
1	TP	1
1	TSF	1
1	UVM	3

Part 2: SP: Ureter, segment of distal left; excised

[page 4 of 4]
[REDACTED]

Block	Sect. Site	PCs
1	R	3
1	SM	1

Part 3: SP:Lymph nodes, para-aortic and preaortic; excision [REDACTED]

Block	Sect. Site	PCs
1	L1	1
1	L2	1
3	LN	7

Part 4: SP:Lymph nodes, left common iliac; excision

Block	Sect. Site	PCs
2	LN	5

Part 5: SP:Lymph nodes, interaortocaval; excision [REDACTED]

Block	Sect. Site	PCs
3	LN	7

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA WITH PAPILLARY FEATURES. [REDACTED]
PERMANENT DIAGNOSIS: SAME [REDACTED]

Source: NCI Genomic Data Commons file 295011cf-a472-448e-b287-aa7a96346314 (TCGA-BQ-5878.001E0E3E-04BD-407A-B65F-D2636EE28886.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).